Surgical pathology report (de-identified scan), TCGA case TCGA-AL-A5DJ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AL-A5DJ-01A (Primary Tumor).

[page 1 of 5]
SPECIMEN:
SURGICAL PATHOLOGY REPORT

DOB:
Sex: F

Location:
Date Collected
Date Received
Physician
Copy To:
Clinical History/Diagnosis: Left renal mass

Source of Specimen(s):

- 1: Left Kidney Mass
- 2: Nodes at Hylum
- 3: Fat at Diaphragm
- 4: Anterior Margin
- 5: Medial Lymph Node Dissection at Apex
- 6: Retroperitoneal Lymph Nodes
- 7: Left Ureter
- 8: Left Kidney

Final Diagnosis:

****AMENDED REPORT****

This amended report is issued to correct the source of specimen in part #1 to left kidney per The requisition slip was incorrectly labeled from the operating room.

1. Left kidney, biopsy:
- High grade carcinoma.
2. Soft tissue at hilum, excision:
- Fatty tissue with high grade carcinoma.
- Lymphoid tissue not identified.
3. Fat at diaphragm, excision:
- Fatty tissue with no tumor seen.
4. Anterior margin, biopsy:
- Fatty tissue with no tumor seen.
5. Medial soft tissue at apex, excision:
- Fatty tissue with no tumor seen.
6. Retroperitoneal soft tissue, excision:
- Fatty tissue with no tumor seen.
7. Left ureter, ureterectomy:
- No tumor seen.

ICD-0-3
Carcinoma, papillary
renal cell 8260/3
Site @ Kidney NOS C64.9
JW 5/24/13

Prior thyroid cancer -
treatment unknown
by JSS.

HI/AA Discrepancy		/
Prior Malignancy History	thyroid	/

[page 2 of 5]
8. Left kidney, total nephrectomy:

- High grade renal cell carcinoma, papillary type II, 6.7 cm.
- Tumor invades through the kidney into the perirenal fat.
- Vein invasion is identified.
- Vascular and ureteral margins with no tumor seen.
- pTNM: T3a Nx Mx

Note: Immunohistochemical stains performed with good positive and negative controls show tumor cells focally positive for RCC, CK19 and vimentin. They are negative for CD10, keratin903, CK5/6 and CD117. This profile is consistent with papillary carcinoma of kidney.

These tests were developed and their performance characteristics determined by the immunohistochemistry laboratory at the

These tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1998 (CLIA) as qualified to perform high complexity clinical testing.

****ORIGINAL REPORT****

1. Right kidney, biopsy:

- High grade carcinoma.

2. Soft tissue at hilum, excision:

- Fatty tissue with high grade carcinoma.
- Lymphoid tissue not identified.

3. Fat at diaphragm, excision:

- Fatty tissue with no tumor seen.

4. Anterior margin, biopsy:

- Fatty tissue with no tumor seen.

5. Medial soft tissue at apex, excision:

- Fatty tissue with no tumor seen.

6. Retroperitoneal soft tissue, excision:

- Fatty tissue with no tumor seen.

7. Left ureter, ureterectomy:

- No tumor seen.

8. Left kidney, total nephrectomy:

- High grade renal cell carcinoma, papillary type II, 6.7 cm.
- Tumor invades through the kidney into the perirenal fat.
- Vein invasion is identified.
- Vascular and ureteral margins with no tumor seen.
- pTNM: T3a Nx Mx

[page 3 of 5]
Note: Immunohistochemical stains performed with good positive and negative controls show tumor cells focally positive for RCC, CK19 and vimentin. They are negative for CD10, keratin903, CK5/6 and CD117. This profile is consistent with papillary carcinoma of kidney.

These tests were developed and their performance characteristics determined by the immunohistochemistry laboratory at the

These tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1998 (CLIA) as qualified to perform high complexity clinical testing.

Gross Description:

Received in eight parts.

Source of Tissue: 1. Labeled #1, "left kidney mass"

Intraoperative Consultation: UROTHELIAL CARCINOMA PER DR.

Gross Description: Received fresh labeled "left kidney mass". It consists of a soft red-brown irregular tissue fragment measuring 1 x 1 x 0.3 cm. Entirely frozen in 1FS.

Source of Tissue: 2. Labeled #2, "nodes at hilum"

Gross Description: Received fresh labeled "nodes at hilum". It consists of two soft yellow-tan irregular fibrofatty tissue fragments measuring 1.5 x 1 x 0.5 cm. The specimen is sectioned to reveal a soft yellow-tan fibrofatty cut surface. Entirely submitted in cassette 2A.

Source of Tissue: 3. Labeled #3, "fat at diaphragm"

Gross Description: Received fresh labeled "fat at diaphragm". It consists of three soft yellow-tan irregular fibrofatty tissue fragments measuring 1.2 x 1 x 0.5 cm in aggregate. Entirely submitted in cassette 3A.

Source of Tissue: 4. Labeled #4, "anterior margin"

Gross Description: Received fresh labeled "anterior margin". It consists of a soft yellow-tan irregular fibrofatty tissue fragment measuring 0.5 x 0.5 x 0.3 cm. Entirely submitted in cassette 4A.

[page 4 of 5]
Source of Tissue: 5. Labeled #5, "medial lymph node dissection at apex"

Gross Description: Received fresh labeled "medial lymph node dissection at apex". It consists of a soft yellow-tan irregular fibrofatty tissue fragment measuring 3 x 2.5 x 0.5 cm. The specimen is sectioned to show a soft yellow-tan fibrofatty cut surface with no masses present. No obvious palpable lymph nodes present.

Entirely submitted in cassettes 5A-5B.

Source of Tissue: 6. Labeled #6, "retroperitoneal lymph nodes"

Gross Description: Received fresh labeled "retroperitoneal lymph nodes". It consists of two soft yellow-tan irregular fibrofatty tissue fragments measuring 4 x 3 x 0.5 cm in aggregate. The specimen is sectioned to reveal a homogeneous, soft yellow-tan fibrofatty cut surface with no palpable lymph nodes present.

Entirely submitted in cassettes 6A-6B.

Source of Tissue: 7. Labeled #7, "left ureter, stitch marks distal end"

Gross Description: Received fresh labeled "left ureter, stitch marks distal end". It consists of a soft tan-pink tubular tissue measuring 10.5 cm in length and 0.5 cm in diameter. The outer surface is inked black. The specimen is serially sectioned to show a smooth tan-pink cut surface with no obvious papillary structures noted. Representative sections are submitted in 7A-7E.

Designation of Sections: 7A- distal resection margin, 7B- proximal resection margin, 7C-7E- random sections taken every 5 cm from distal to proximal

Source of Tissue: 8. Labeled #8, "left kidney, stitch marks area of gross tumor protruding outside of kidney"

Gross Description: Received fresh labeled "left kidney, stitch marks area of gross tumor protruding outside of kidney". It consists of a kidney with surrounding perinephric fat weighing a total of 290 grams and measuring 13.5 x 9.5 x 5.5 cm. The orientation suture is identified. The attached ureter measures 9.5 cm in length and 0.5 cm in diameter. The ureter is opened to reveal a smooth tan-pink mucosal lining with no ulcerations or polyps present. The kidney is bisected to show a 6.7 x 5.5 x 5 cm ill-defined fleshy papillary tumor located predominantly at the superior and mid pole aspect of the specimen. The sutured area and surrounding fat margin closest to tumor are inked green. The ureteropelvic junction appears unremarkable. The anterior pole and approximately 60% of the renal pelvis also appears unremarkable. The tumor comes within less than 0.1 cm of the closest capsule. Tissue submitted to tumor bank and representative sections are submitted in

[page 5 of 5]
Designation of Sections: 8A- urethral and vascular margins, 8B- additional random section of ureter, 8C- ureteropelvic junction, 8D-8E- protruding section of tumor through outside of kidney, 8F-8H- tumor with closest surrounding capsule, 8I-8J- tumor with adjacent uninvolved renal pelvis

Procedures/Addenda

Addendum	Date Ordered:	Status.
----------	---------------	---------

Date Complete. By:

Date Reported

Addendum Diagnosis

Because of patient's history of thyroid cancer, at the request of _____, the renal lesion was stained with antibodies TTF-1, thyroglobulin and pan keratin. Positive and negative control slides are satisfactory. Tumor is positive for keratin and negative for TTF-1 and thyroglobulin. The diagnosis of kidney cancer is unchanged.

These tests were developed and their performance characteristics determined by the immunohistochemistry laboratory at the

..... These tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1998 (CLIA) as qualified to perform high complexity clinical testing.

Source: NCI Genomic Data Commons file 59d00a62-f86e-4e88-99a6-b789279685c4 (TCGA-AL-A5DJ.040C3F06-62E5-4287-A499-3BB36C4BAD08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).